Gene-level copy-number profile of tumor specimen C3L-04011-04 from CPTAC case C3L-04011, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.3 years (21,276 days).
Specimen C3L-04011-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 91586c6f-6f67-44e5-a02e-f03ed3f20821.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04011-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/3ca5e2a0-15bf-44a1-8956-5274c7af95b1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,377; copy number 2: 48,165; copy number 3: 3,211; copy number 4: 65; copy number 5: 102; copy number 6: 65; copy number 7: 4; copy number 8: 4; copy number 9: 17; copy number 10: 22; copy number 11: 52; copy number 12: 23; copy number 13: 7; copy number 14: 9; copy number 15: 31; copy number 16: 24; copy number 17: 3; copy number 18: 17; copy number 19: 19; copy number 20: 26; copy number 21: 6; copy number 22: 13; copy number 23: 9; copy number 25: 1; copy number 26: 23; copy number 27: 24; copy number 28: 20; copy number 29: 9; copy number 30: 9; copy number 32: 10; copy number 34: 1; copy number 35: 3; copy number 36: 8; copy number 41: 5; copy number 49: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 570 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:7,287,924–7,830,081, 10 genes, copy number 6–9: AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2, AC093305.1.
- chr5:23,951,348–24,353,443, 7 genes, copy number 5–6: C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1.
- chr5:24,749,374–24,910,695, 7 genes, copy number 5: AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA.
- chr5:26,382,519–30,248,893, 34 genes, copy number 5–34: AC025475.1, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2.
- chr5:31,053,565–31,595,669, 9 genes, copy number 7–14: RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, Y_RNA, C5orf22, AC022417.1, RNU6-363P.
- chr5:32,531,633–32,888,145, 4 genes, copy number 5–8: SUB1, LINC02061, NPR3, AC025459.1.
- chr5:33,424,025–34,158,767, 16 genes, copy number 5–14: AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1.
- chr5:35,048,756–35,230,487, 1 gene, copy number 12 (within-gene range 3–12): PRLR.
- chr5:35,429,064–40,067,200, 77 genes, copy number 6–49 (broad region; genes not listed).
- chr5:40,512,333–43,525,310, 61 genes, copy number 5–32 (broad region; genes not listed).
- chr9:7,477,045–7,598,377, 2 genes, copy number 12: RPL4P5, PPIAP33.
- chr12:44,498,616–44,499,158, 1 gene, copy number 10: AC025253.1.
- chr12:47,075,707–47,346,297, 10 genes, copy number 11–18: AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1.
- chr12:47,593,208–47,837,898, 15 genes, copy number 11: AC004486.1, RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354.
- chr12:51,047,962–51,217,708, 9 genes, copy number 15: LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1.
- chr12:54,497,752–54,648,493, 7 genes, copy number 12: NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD.
- chr12:55,113,077–55,312,757, 11 genes, copy number 5: OR9K1P, AC027287.1, OR9K2, OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P.
- chr12:56,202,179–56,959,374, 44 genes, copy number 5: RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS, MIP, AC097104.1, SPRYD4, GLS2, HSPD1P4, RBMS2, RNU6-343P, BAZ2A, ATP5F1B, SNORD59A, PTGES3, RN7SL809P, NACA, AC117378.1, PRIM1, HSD17B6, AC121758.2, AC121758.4, AC121758.3, AC121758.1, SDR9C7, AC026120.2, RDH16.
- chr12:57,253,762–58,813,060, 58 genes, copy number 13–27 (within-gene range 1–27): R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388.
- chr12:59,322,765–59,812,576, 9 genes, copy number 6–35: AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1.
- chr12:63,142,759–63,272,336, 3 genes, copy number 7: AVPR1A, AC135584.1, HNRNPA1P69.
- chr12:66,950,754–67,753,817, 14 genes, copy number 6–16: AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1.
- chr12:68,610,855–70,443,923, 48 genes, copy number 11–18: RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P.
- chr12:80,402,178–80,937,925, 9 genes, copy number 5–17 (within-gene range 4–17): PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1.
- chr12:111,686,053–113,438,276, 53 genes, copy number 19–28 (within-gene range 19–39): ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11, RPH3A, MIR1302-1, OAS1, AC004551.1, OAS3, OAS2, IMMP1LP2, RPS15AP32, DTX1, RASAL1, CFAP73, Y_RNA, DDX54, MIR7106, Y_RNA, RITA1, AC089999.1, IQCD, TPCN1, AC089999.2, MIR6762, SLC8B1, PLBD2, SDS, SDSL.
- chr12:113,789,542–113,789,807, 1 gene, copy number 19: DYNLL1P4.
- chr12:118,645,315–120,440,737, 50 genes, copy number 6–30 (within-gene range 2–30): LINC02460, RPL17P37, LINC02423, LINC02440, LINC02439, RNA5SP374, AC087863.2, AC087863.1, SRRM4, AC087885.1, RN7SL508P, AC084361.1, HSPB8, AC084880.4, AC084880.3, AC084880.1, AC084880.2, LINC00934, CCDC60, AC002070.1, TMEM233, RN7SKP197, PRKAB1, CIT, AC002563.1, MIR1178, RPL35AP30, BICDL1, Metazoa_SRP, AC004812.1, RAB35, AC004812.2, GCN1, MIR4498, RPLP0, PXN-AS1, PXN, AC004263.2, AC004263.1, RPS20P31, NME2P1, RNU4-2, RNU4-1, SIRT4, RNU6-1088P, PLA2G1B, MSI1, RPS27P25, AC003982.1, COX6A1.

Autosomal genes at a single copy (total copy number 1): 6,377. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
